Somatic mutation profile of tumor specimen CPT000400 (aliquot CPT000400-0013) from CPTAC case 05BR055, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 84.6 years (30,903 days).
Specimen CPT000400: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef21851c-40c6-4083-9792-c5d910e96e37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000404 (Blood Derived Normal), aliquot CPT000404-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9672b176-2de4-430e-a249-7f372aaadba1

The open-access MAF lists 151 somatic variants for this specimen: 110 protein-altering or splice-affecting, 26 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 26, Intron 9, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, RNA 2, 5'UTR 2, Splice Region 2, 5'Flank 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.4078C>T p.R1360W | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768328938, COSV52204487; called by muse, mutect2, varscan2
- ACAD8 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 23/370 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99844123; called by muse, mutect2
- ANKRD17 | c.5376G>C p.L1792F | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58218310; called by muse, mutect2, varscan2
- AURKB | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100298922; called by muse, varscan2
- BARX2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs148147759; called by muse, mutect2, varscan2
- C10orf71 | c.3161C>T p.A1054V | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104406844, COSV60509542; called by muse, mutect2, varscan2
- C4orf54 | c.3776C>T p.A1259V | Missense Mutation (SNP) | VAF 71/523 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1482535952; called by muse, mutect2, varscan2
- CNTNAP2 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 87/344 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs758221358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.3757A>G p.I1253V | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs762144088; called by muse, mutect2, varscan2
- CYP39A1 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as rs762814859; called by muse, mutect2, varscan2
- DIDO1 | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768988305; called by muse, mutect2, varscan2
- DPY19L2 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs754869560, COSV100116779; called by muse, varscan2
- FAM189B | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs572393078; called by muse, mutect2, varscan2
- FAT1 | c.8943G>T p.K2981N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV71673666; called by muse, mutect2, varscan2
- FERMT3 | c.1568G>A p.R523Q (on ENST00000279227 / NM_178443.3; = p.R519Q on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1383121861, COSV54178776; called by muse, mutect2, varscan2
- FGD3 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1184428064, COSV61597412; called by muse, mutect2, varscan2
- GCM1 | c.78C>T p.N26= | Splice Region (SNP) | VAF 32/195 reads (16%) | catalogued as rs984489102, COSV52520833; called by muse, mutect2, varscan2
- IGLV1-44 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 249/540 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as rs369704003; called by muse, mutect2, varscan2
- ITGAV | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs201898547; called by muse, mutect2, varscan2
- LRP1 | c.9865G>A p.V3289M | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs764000429; called by muse, mutect2, varscan2
- LTO1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs574166254, COSV57120070; called by muse, mutect2, varscan2
- METTL8 | c.550G>C p.G184R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV100930963; called by muse, mutect2, varscan2
- MYO3A | c.1792T>C p.Y598H | Missense Mutation (SNP) | VAF 71/505 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886046923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDST3 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as COSV56629090; called by muse, mutect2
- NR2E3 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 122/439 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs368030775, COSV58910545; called by muse, mutect2, varscan2
- ORM2 | c.264C>G p.N88K | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs775419670, COSV99407743; called by muse, mutect2, varscan2
- PCDHA7 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 200/978 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs1554135772, COSV65343760, COSV65346769; called by mutect2, varscan2
- PDGFRA | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57272637; called by muse, mutect2, varscan2
- PGAP6 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs185733391; called by muse, mutect2, varscan2
- PIK3R5 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs751327217; called by muse, varscan2
- PLEC | c.8704C>T p.H2902Y (on ENST00000322810 / NM_201380.4; = p.H2792Y on NM_000445.5) | Missense Mutation (SNP) | VAF 63/796 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs1554686100; called by muse, mutect2
- PLEKHH1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs765515437, COSV61286118; called by muse, mutect2, varscan2
- PLOD1 | c.1259G>C p.G420A | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99538287; called by muse, mutect2
- PNKP | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 93/501 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV55586327; called by muse, mutect2, varscan2
- POSTN | c.728C>G p.A243G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV65714469; called by muse, mutect2, varscan2
- PPP1R32 | c.108C>T p.Y36= | Splice Region (SNP) | VAF 6/48 reads (13%) | catalogued as rs763603391; called by mutect2, varscan2
- PRKCZ | c.1180G>C p.D394H | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66066029; called by muse, mutect2, varscan2
- PROKR1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs771784209, COSV58137160; called by muse, mutect2, varscan2
- PUS7 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.338); catalogued as rs1418106358; called by muse, mutect2, varscan2
- RYR2 | c.4274C>T p.T1425M | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs761181641, COSV63661890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A11 | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 68/380 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as rs1452388879; called by muse, mutect2, varscan2
- SLC6A2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV54914722; called by muse, mutect2, varscan2
- SON | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs752533651, COSV51657286; called by muse, mutect2, varscan2
- SPNS1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs199561184, COSV57954148; called by muse, mutect2, varscan2
- SUN2 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 281/532 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as rs760492857; called by muse, mutect2, varscan2
- SYT8 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs202139873, COSV99425429; called by muse, mutect2, varscan2
- TBR1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs1413114353, COSV67418288; called by muse, mutect2, varscan2
- TMEM171 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as rs761332689, COSV55129962; called by muse, mutect2
- TMPRSS11D | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as COSV52226373; called by muse, mutect2, varscan2
- TRPC7 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1217066417, COSV61453241, COSV61463013; called by muse, mutect2, varscan2
- UNC79 | c.4615G>A p.A1539T (on ENST00000393151 / NM_001346218.2; = p.A1362T on NM_020818.5) | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1295040314; called by muse, mutect2, varscan2
- ZNF154 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs775306046, COSV70745044, COSV70745338; called by muse, mutect2, varscan2
- AGBL1 | c.1667G>A p.R556K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALDOA | c.658G>A p.E220K (on ENST00000642816 / NM_001243177.4; = p.E166K on NM_184041.5) | Missense Mutation (SNP) | VAF 111/629 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALG12 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 138/430 reads (32%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKRD11 | c.2566G>A p.D856N | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GNT6 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- BEND2 | c.26-2A>G p.X9_splice | Splice Site (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- BMP2K | c.2710A>T p.S904C | Missense Mutation (SNP) | VAF 103/258 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- C10orf71 | c.3595G>A p.E1199K | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2
- CCDC171 | c.2996A>T p.E999V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDC45 | c.530G>T p.W177L | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- COL22A1 | c.1197G>C p.Q399H | Missense Mutation (SNP) | VAF 48/605 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2
- CORO7 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRH | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 55/523 reads (11%) | called by muse, mutect2, varscan2
- CXCR4 | c.805A>C p.I269L | Missense Mutation (SNP) | VAF 106/453 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP2J2 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DIS3L2 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- EPB41L1 | c.1145C>G p.P382R | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FKBP4 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- HECW1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HLA-DQB2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 120/722 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HSPA1L | c.1718del p.L573Wfs*68 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- KAT6A | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNK17 | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- KLHL12 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2C | c.5320G>C p.E1774Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LTB | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- LYPD4 | c.356C>G p.T119S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LYPLA1 | c.519T>G p.C173W | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- MAP4K5 | c.966del p.R322Sfs*16 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | called by mutect2, pindel, varscan2
- MOV10 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OPRD1 | c.605T>G p.F202C | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OXER1 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- P3H3 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PFKFB4 | c.1046C>G p.A349G | Missense Mutation (SNP) | VAF 32/161 reads (20%) | PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PIK3R3 | c.315-3_315-2del p.X105_splice | Splice Site (DEL) | VAF 5/53 reads (9%) | called by pindel, varscan2
- PIR | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1L1 | c.6760C>A p.R2254S | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- POLR2G | c.53T>C p.F18S | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PRAMEF4 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 100/502 reads (20%) | called by muse, mutect2, varscan2
- PRKCZ | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM12 | c.1642A>G p.I548V | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- RTN4RL2 | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- RYR1 | c.12094G>T p.G4032W | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SACS | c.3986C>G p.S1329* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- SPRED3 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- SPTB | c.6351A>T p.E2117D | Missense Mutation (SNP) | VAF 120/606 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TAS1R1 | c.2273A>G p.E758G | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TATDN2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TBL1X | c.84dup p.Q29Sfs*21 | Frame Shift Ins (INS) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- TEX10 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.265); called by muse, mutect2
- TIMP2 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TMED5 | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFSF10 | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TP53 | c.926_933del p.P309Hfs*25 | Frame Shift Del (DEL) | VAF 111/200 reads (56%) | called by mutect2, pindel, varscan2
- ULBP3 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 40/596 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.325); called by muse, mutect2
- VCPIP1 | c.1597A>C p.S533R | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- VPS50 | c.464T>C p.L155S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZEB1 | c.303T>G p.D101E | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- AAK1 | c.1659A>G p.Q553= | Silent (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- ANKRD12 | c.4884C>T p.V1628= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs753903213; called by muse, mutect2, varscan2
- ATP2A1 | c.1977C>T p.D659= | Silent (SNP) | VAF 28/372 reads (8%) | catalogued as rs1263928253; called by muse, mutect2
- AURKB | c.963C>G p.V321= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, varscan2
- BRWD1 | c.3006A>G p.Q1002= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs1450685355; called by muse, mutect2, varscan2
- CEACAM7 | c.675C>T p.S225= | Silent (SNP) | VAF 47/296 reads (16%) | catalogued as rs1555810907; called by muse, mutect2, varscan2
- CPT1A | c.1833G>A p.E611= | Silent (SNP) | VAF 26/360 reads (7%) | called by muse, mutect2
- GRM8 | c.228G>T p.L76= | Silent (SNP) | VAF 76/347 reads (22%) | called by muse, mutect2, varscan2
- HELZ2 | c.312C>T p.T104= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as rs1412005811; called by muse, mutect2, varscan2
- KBTBD12 | c.1545C>T p.D515= | Silent (SNP) | VAF 99/222 reads (45%) | catalogued as rs751500751; called by muse, mutect2, varscan2
- LDB3 | c.714C>T p.A238= | Silent (SNP) | VAF 123/430 reads (29%) | catalogued as rs727503125, COSV53945426; ClinVar: likely benign; called by muse, mutect2, varscan2
- LILRB1 | c.1971T>G p.S657= (on ENST00000427581; = p.S606= on NM_006669.6) | Silent (SNP) | VAF 39/964 reads (4%) | called by muse, mutect2
- LRP5 | c.2463C>T p.T821= | Silent (SNP) | VAF 29/263 reads (11%) | catalogued as rs778180589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC19 | c.624G>A p.T208= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs775260295; called by muse, mutect2, varscan2
- NEO1 | c.1518G>A p.A506= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs1172237081, COSV56071262; called by muse, mutect2, varscan2
- NRGN | c.60G>A p.P20= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV99423402; called by muse, mutect2
- PFAS | c.720C>T p.H240= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as rs541236125; called by muse, mutect2, varscan2
- PIP5K1A | c.477T>C p.D159= (on ENST00000368888 / NM_001135638.2; = p.D146= on NM_003557.3) | Silent (SNP) | VAF 34/192 reads (18%) | called by muse, mutect2, varscan2
- RUSC1 | c.94C>T p.L32= | Silent (SNP) | VAF 27/198 reads (14%) | called by muse, mutect2, varscan2
- SLC17A8 | c.882G>C p.G294= | Silent (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- SLC7A6 | c.549C>G p.A183= | Silent (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- SP140 | c.1431G>A p.A477= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs182891771, COSV59452439; called by muse, mutect2, varscan2
- TLL1 | c.687C>T p.G229= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- TRPS1 | c.2469G>A p.Q823= (on ENST00000220888 / NM_001330599.2; = p.Q836= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/1238 reads (5%) | called by muse, mutect2
- TRPS1 | c.2286G>A p.E762= (on ENST00000220888 / NM_001330599.2; = p.E775= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/1394 reads (6%) | catalogued as rs1158536861; called by muse, mutect2
- UCK2 | c.768C>T p.S256= | Silent (SNP) | VAF 15/406 reads (4%) | catalogued as rs1160479070, COSV63316869; called by muse, mutect2
- AC073343.1 | n.125C>T | RNA (SNP) | VAF 21/107 reads (20%) | catalogued as rs911877036; called by muse, mutect2, varscan2
- AC244394.2 | n.1481G>C | RNA (SNP) | VAF 36/284 reads (13%) | called by muse, mutect2
- BRF2 | c.537-508C>G | Intron (SNP) | VAF 146/314 reads (46%) | called by muse, mutect2, varscan2
- CLIP3 | c.919-17C>A | Intron (SNP) | VAF 56/266 reads (21%) | called by muse, mutect2, varscan2
- FAAP20 | c.470+695C>G | Intron (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- GLIS3 | c.1408-358C>A | Intron (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- HBA2 | c.301-36C>T | Intron (SNP) | VAF 42/616 reads (7%) | catalogued as rs374396930; called by muse, mutect2
- HOMER3 | c.*6G>T | 3'UTR (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- MYT1 | c.1847-43C>G | Intron (SNP) | VAF 64/396 reads (16%) | catalogued as rs750404537; called by muse, mutect2, varscan2
- SLC23A1 | c.-25A>T | 5'UTR (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-26050G>A | Intron (SNP) | VAF 54/244 reads (22%) | catalogued as rs1402841542; called by muse, mutect2, varscan2
- SPATA20 | c.78-179C>T | Intron (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- STEAP1 | c.762+911A>T | Intron (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- TLCD1 | chr17:28726785 C>T | 5'Flank (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- TMC8 | c.-103G>A | 5'UTR (SNP) | VAF 40/201 reads (20%) | catalogued as rs969881722; called by muse, mutect2, varscan2
